Surgical pathology report (de-identified scan), TCGA case TCGA-85-A510, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-A510-01A (Primary Tumor).

ICD-0-3

Carcinoma, squamous cell, NOS 8070/3
Site: lung, @ lower lobe 634.3

hw
11/8/12

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: LUNG TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor site: Lung

Tumor size: 6 x 6 x 6 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: 2/2 positive for metastasis (Intrathoracical 2/2)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Left- lower

Crit. In	Yes	No
HR AA Discrepancy		
Other Malignancy History		

Source: NCI Genomic Data Commons file 6a3e5229-fc35-4f79-a969-ae9a5a4edaa4 (TCGA-85-A510.4F6022A3-A5E0-4124-B740-E9BB9A301102.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).